Gene-level copy-number profile of tumor specimen TCGA-BS-A0TE-01A from TCGA case TCGA-BS-A0TE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Corpus uteri; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 35.5 years (12,983 days).
Specimen TCGA-BS-A0TE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a0f910d2-657e-4458-9ebd-047c2ff4646a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BS-A0TE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a0ceffe5-3810-4627-835f-7c344ccb3704

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 5; copy number 2: 29,384; copy number 3: 4,400; copy number 4: 17,062; copy number 5: 488; copy number 6: 8,316; copy number 8: 93.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BS-A0TE-01A-11D-A102-01): tumor purity 0.76, ploidy 1.43, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–140,992,659, 1 gene: Y_RNA.
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr4:187,408,232–188,389,666, 17 genes: LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3, AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1.
- chr10:87,500,337–89,139,458, 41 genes: AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,897 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–197,341, 4 genes, copy number 6: LINC01986, AC066595.1, CHL1-AS2, AC066595.2.
- chr3:282,689–282,792, 1 gene, copy number 6: RNU6-1194P.
- chr3:78,038,705–113,947,570, 366 genes, copy number 6 (broad region; genes not listed).
- chr3:152,457,759–198,222,513, 800 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:89,410,960–89,999,409, 9 genes, copy number 6 (within-gene range 2–6): AC093866.1, AC097478.4, SNCA, AC097478.1, AC097478.3, AC097478.2, SNCA-AS1, MMRN1, AC105445.1.
- chr4:90,370,123–90,370,427, 1 gene, copy number 6: RN7SKP248.
- chr6:28,188,050–33,080,775, 377 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:41,189,749–44,450,425, 137 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 6 (broad region; genes not listed).
- chr8:150,584–138,497,261, 2,267 genes, copy number 6 (broad region; genes not listed).
- chr8:139,727,725–145,066,685, 207 genes, copy number 6 (broad region; genes not listed).
- chr9:60,914,407–67,797,500, 161 genes, copy number 5–6 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 6–8 (broad region; genes not listed).
- chr22:48,044,710–50,801,309, 95 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
